Somatic mutation profile of tumor specimen 0DKSZB from CCDI case PBBYRS, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 14.6 years (5,324 days).
Specimen 0DKSZB: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 277d17d3-3640-4355-a568-58ee28093169.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DKSTU (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/048c04a2-96a1-4bfb-bb8c-558f8b08730c

The open-access MAF lists 5 somatic variants for this specimen: 5 protein-altering or splice-affecting.
By variant classification: Splice Site 2, Missense Mutation 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KMT2D | c.14861C>T p.S4954L | Missense Mutation (SNP) | VAF 42/798 reads (5%) | SIFT tolerated (0.15); PolyPhen benign (0.321); catalogued as rs1565761336, CM138439; called by muse, mutect2
- MYH1 | c.4531+1G>A p.X1511_splice | Splice Site (SNP) | VAF 37/524 reads (7%) | catalogued as rs375833331; called by muse, mutect2
- ADAMDEC1 | c.284+2T>A p.X95_splice | Splice Site (SNP) | VAF 22/568 reads (4%) | called by muse, mutect2
- IL10RA | c.1061del p.P354Lfs*26 | Frame Shift Del (DEL) | VAF 211/640 reads (33%) | called by mutect2, pindel, varscan2
- SKIDA1 | c.1885G>C p.E629Q | Missense Mutation (SNP) | VAF 38/915 reads (4%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.028); called by muse, mutect2
